Somatic mutation profile of tumor specimen C3N-00209-03 (aliquot CPT0084690010) from CPTAC case C3N-00209, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 81.7 years (29,831 days).
Specimen C3N-00209-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28f10dd9-056f-4721-ae92-1af787de428e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00209-31 (Blood Derived Normal), aliquot CPT0085330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4b88f8a-ef49-4bcf-90e8-3cfa68cd8904

The open-access MAF lists 1,115 somatic variants for this specimen: 730 protein-altering or splice-affecting, 344 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 658, Silent 344, Nonsense Mutation 47, Intron 24, Splice Region 13, Splice Site 7, 3'UTR 6, RNA 5, 5'Flank 3, 3'Flank 3, Frame Shift Del 2, Translation Start Site 2.

Variants (750 of 1,115; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 112/217 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AATK | c.3857C>T p.S1286F (on ENST00000326724 / NM_001080395.3; = p.S1183F on NM_004920.2) | Missense Mutation (SNP) | VAF 288/390 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1473188124; called by muse, varscan2
- ABCA13 | c.13691C>T p.S4564L | Missense Mutation (SNP) | VAF 122/356 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs752049932, COSV68946353; called by muse, mutect2, varscan2
- ABCB1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV55964105, COSV99712849; called by muse, mutect2, varscan2
- ACO1 | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 92/187 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs1218281501, COSV59383207; called by muse, mutect2, varscan2
- ACO1 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 95/188 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1027207166; called by muse, mutect2, varscan2
- ACSS3 | c.1441G>C p.G481R | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54094515; called by muse, varscan2
- ACTR10 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54298803; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 154/351 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1468282818; called by muse, mutect2, varscan2
- ADGRG7 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs373804273, COSV56297862; called by muse, varscan2
- AL645922.1 | c.1445G>A p.W482* | Nonsense Mutation (SNP) | VAF 114/307 reads (37%) | catalogued as rs757959803; called by muse, mutect2, varscan2
- ALPI | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 127/398 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs753905708, COSV55015387, COSV55016013; called by muse, mutect2, varscan2
- ALPI | c.1182C>T p.F394= | Splice Region (SNP) | VAF 80/222 reads (36%) | catalogued as rs759088255, COSV55014638; called by muse, varscan2
- ALPK2 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 98/180 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184186856, COSV100864540; called by muse, varscan2
- ALPK3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 165/544 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs745476445; called by muse, varscan2
- ALS2CL | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 164/499 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs141179686; called by muse, mutect2, varscan2
- AMPD3 | c.697G>A p.D233N (on ENST00000396553 / NM_001025389.2; = p.D242N on NM_000480.3) | Missense Mutation (SNP) | VAF 130/412 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs866866033; called by muse, varscan2
- ANGPTL4 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 169/507 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.11); catalogued as rs373782424; called by muse, mutect2, varscan2
- ANGPTL4 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 170/506 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV56845282; called by muse, mutect2, varscan2
- ANGPTL6 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 135/400 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs890794109, COSV53463732; called by muse, mutect2, varscan2
- ANKRD2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs752768813; called by muse, mutect2, varscan2
- ANPEP | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 84/318 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); catalogued as COSV100263398; called by muse, varscan2
- AP006621.6 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 150/418 reads (36%) | PolyPhen possibly damaging (0.833); catalogued as rs1477440155; called by muse, varscan2
- APAF1 | c.3487C>T p.H1163Y (on ENST00000551964 / NM_181861.2; = p.H1109Y on NM_001160.3) | Missense Mutation (SNP) | VAF 110/331 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as rs1336392953; called by muse, mutect2, varscan2
- APBB1IP | c.485A>T p.K162I | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63303178; called by muse, mutect2
- APC2 | c.2354C>T p.S785L | Missense Mutation (SNP) | VAF 231/596 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs955618059; called by muse, mutect2, varscan2
- APOBEC1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs267603686, COSV57548632; called by muse, mutect2, varscan2
- AQP9 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.03); catalogued as COSV54970993; called by muse, mutect2, varscan2
- ARHGAP36 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 169/236 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1460939004, COSV52263824; called by muse, varscan2
- ARMC4 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV53466312; called by muse, mutect2
- ASPHD2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 124/354 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1215761224, COSV53218070, COSV53220289; called by muse, varscan2
- ATP13A4 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 120/357 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs200876454; called by muse, varscan2
- B4GALNT3 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 111/326 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV56755916; called by muse, mutect2, varscan2
- BCL2A1 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 125/509 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs866382665; called by muse, mutect2, varscan2
- C12orf42 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as rs773446119, COSV59378762; called by muse, mutect2, varscan2
- C12orf50 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 96/289 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.568); catalogued as rs759969576, COSV53896713; called by muse, mutect2, varscan2
- C6 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 77/271 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282235295, COSV54718037; called by muse, mutect2, varscan2
- CACNA1D | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 79/295 reads (27%) | catalogued as COSV55441099; called by muse, varscan2
- CACNA1D | c.1537C>T p.R513C (on ENST00000350061 / NM_001128840.3; = p.R533C on NM_000720.4) | Missense Mutation (SNP) | VAF 119/344 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751711138; called by muse, mutect2, varscan2
- CACNA1E | c.5074G>A p.E1692K | Missense Mutation (SNP) | VAF 137/421 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as rs770455581, COSV62437732; called by muse, mutect2, varscan2
- CACNA1H | c.5467C>T p.R1823C | Missense Mutation (SNP) | VAF 124/350 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs60760436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs375121955, COSV54944517; called by muse, varscan2
- CALCR | c.727C>T p.Q243* (on ENST00000649521 / NM_001164737.2; = p.Q227* on NM_001742.4) | Nonsense Mutation (SNP) | VAF 89/327 reads (27%) | catalogued as COSV64006993; called by muse, mutect2, varscan2
- CAPZA3 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 144/395 reads (36%) | catalogued as rs1189957548, COSV56848485; called by muse, mutect2, varscan2
- CARMIL3 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 94/326 reads (29%) | catalogued as rs771031430, COSV100549998; called by muse, varscan2
- CBX7 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV53358663; called by muse, varscan2
- CCDC168 | c.17692G>A p.G5898R | Missense Mutation (SNP) | VAF 326/569 reads (57%) | SIFT tolerated (0.57); PolyPhen benign (0.224); catalogued as rs776531618; called by muse, varscan2
- CCDC186 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs763349289; called by muse, mutect2
- CCDC60 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs867385001, COSV59548206; called by muse, mutect2, varscan2
- CCDC73 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58801125; called by muse, mutect2, varscan2
- CCDC73 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58795949; called by muse, varscan2
- CCR1 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99946707; called by muse, varscan2
- CD163L1 | c.4339C>T p.P1447S | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.447); catalogued as COSV58013995; called by muse, mutect2, varscan2
- CDH12 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 205/484 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs767086583, COSV101202996, COSV66398117; called by muse, mutect2, varscan2
- CDH6 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs757234769, COSV54068487; called by mutect2, varscan2
- CDH9 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 117/274 reads (43%) | catalogued as COSV50538651; called by muse, mutect2, varscan2
- CDH9 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as rs868604878, COSV50254395, COSV50326277; called by muse, varscan2
- CEP126 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 138/347 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1199212536; called by muse, mutect2, varscan2
- CHGA | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1019977498; called by muse, mutect2, varscan2
- CHKB | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 148/426 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs387907068, CM114049; called by muse, varscan2
- CIZ1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 130/238 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs1374544735, COSV99476801; called by muse, mutect2, varscan2
- CLDN3 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 153/446 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs781978821; called by muse, mutect2, varscan2
- CNTN5 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54280074; called by muse, varscan2
- CNTN5 | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 91/325 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866244785, COSV54341831; called by muse, mutect2, varscan2
- CNTNAP2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 114/353 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62143246; called by muse, mutect2, varscan2
- COL10A1 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 134/252 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54574778; called by muse, varscan2
- COL12A1 | c.8368C>T p.P2790S | Missense Mutation (SNP) | VAF 132/235 reads (56%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.98); catalogued as COSV59394835; called by muse, varscan2
- COL14A1 | c.2796G>A p.M932I | Missense Mutation (SNP) | VAF 51/335 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as rs1442450833; called by muse, mutect2, varscan2
- COL15A1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 138/250 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs763285450, COSV66649143; called by muse, varscan2
- COL26A1 | c.608C>T p.P203L (on ENST00000313669 / NM_001278563.3; = p.P201L on NM_133457.4) | Missense Mutation (SNP) | VAF 100/339 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.528); catalogued as rs950356475; called by muse, mutect2, varscan2
- COL4A4 | c.3256C>T p.P1086S | Missense Mutation (SNP) | VAF 99/282 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs1286834392; called by muse, varscan2
- CPN2 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 148/433 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV60471282; called by muse, mutect2, varscan2
- CPS1 | c.4468C>T p.H1490Y | Missense Mutation (SNP) | VAF 104/313 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs1393116118, COSV51818404; called by muse, mutect2, varscan2
- CRY2 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 130/415 reads (31%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.021); catalogued as rs1357427690; called by muse, varscan2
- CSMD1 | c.3941G>A p.G1314E (on ENST00000520002; = p.G1313E on NM_033225.6) | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1416089699, COSV59333324; called by muse, mutect2, varscan2
- CSMD1 | c.3089C>T p.S1030L (on ENST00000520002; = p.S1029L on NM_033225.6) | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773842728, COSV59282220; called by muse, mutect2
- CSMD1 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV68168191; called by muse, mutect2, varscan2
- CTCFL | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 124/465 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs762680387, COSV54777515; called by muse, mutect2, varscan2
- CTNND2 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 101/252 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs974260134; called by muse, mutect2, varscan2
- CUBN | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64720657; called by muse, mutect2
- CWC15 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 83/227 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs1555096194; called by muse, mutect2, varscan2
- CWC22 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 99/303 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs867630945, COSV55429540; called by muse, mutect2, varscan2
- CYP2C18 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as COSV53675217; called by muse, mutect2
- CYP2E1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.886); catalogued as rs1007026512; called by muse, mutect2, varscan2
- DAO | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); catalogued as COSV99948801; called by muse, mutect2, varscan2
- DAOA | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 145/584 reads (25%) | catalogued as rs1461859694, COSV100298880; called by muse, mutect2, varscan2
- DBX2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 89/291 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs573052950; called by muse, mutect2, varscan2
- DCAF4L2 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 242/434 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763393493, COSV60480956; called by muse, varscan2
- DCC | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 120/258 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1347472471, COSV59102520, COSV59116428; called by muse, mutect2, varscan2
- DEFB116 | c.110G>A p.W37* | Nonsense Mutation (SNP) | VAF 125/333 reads (38%) | catalogued as rs866837026; called by muse, mutect2, varscan2
- DEPDC5 | c.2579C>T p.S860F (on ENST00000400246; = p.S929F on NM_014662.5) | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99836336; called by muse, mutect2, varscan2
- DHDH | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 112/346 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs1158666356, COSV55481662; called by muse, varscan2
- DMBT1 | c.3236C>T p.S1079F (on ENST00000338354 / NM_001377530.1; = p.S580F on NM_004406.3) | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.957); catalogued as rs755146462; called by muse, mutect2
- DMBT1 | c.3284C>T p.S1095F (on ENST00000338354 / NM_001377530.1; = p.S596F on NM_004406.3) | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs766342819; called by muse, mutect2
- DNHD1 | c.12911G>A p.W4304* | Nonsense Mutation (SNP) | VAF 92/258 reads (36%) | catalogued as rs1412593346, COSV99600346; called by muse, mutect2, varscan2
- DOK2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV52388529, COSV52389272; called by muse, varscan2
- DOP1B | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as rs1476710167; called by muse, varscan2
- DPP8 | c.133C>T p.R45W (on ENST00000341861 / NM_001320875.2; = p.R29W on NM_017743.6) | Missense Mutation (SNP) | VAF 146/528 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.2); catalogued as rs769647476; called by muse, mutect2, varscan2
- DUSP21 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 144/223 reads (65%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.91); catalogued as COSV59133829; called by muse, varscan2
- ECPAS | c.4546C>T p.R1516* | Nonsense Mutation (SNP) | VAF 82/152 reads (54%) | catalogued as COSV52202117; called by muse, mutect2, varscan2
- EHHADH | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 113/278 reads (41%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.924); catalogued as COSV51630827; called by muse, varscan2
- EML6 | c.5464G>A p.D1822N | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62865564; called by muse, mutect2, varscan2
- ENTPD1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 125/281 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV100967703; called by muse, mutect2, varscan2
- EPHX4 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 94/167 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV64889126; called by muse, mutect2, varscan2
- EPS8L3 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 115/211 reads (55%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100719756; called by muse, mutect2, varscan2
- ERBB3 | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 139/393 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs147206496; called by muse, varscan2
- EYA1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as rs1389336466, COSV58173650; called by muse, varscan2
- EYA4 | c.989G>A p.G330E (on ENST00000531901 / NM_001301013.1; = p.G324E on NM_004100.5) | Missense Mutation (SNP) | VAF 108/153 reads (71%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); catalogued as rs1331510993; called by muse, mutect2, varscan2
- FAM81B | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as rs199697879; called by muse, varscan2
- FCRL2 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.152); catalogued as COSV63832829; called by muse, varscan2
- FCRL5 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100708640; called by muse, mutect2, varscan2
- FHOD3 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 85/169 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs1297832747; called by muse, mutect2, varscan2
- FIZ1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 174/484 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs775380409, COSV99684379; called by muse, mutect2, varscan2
- FLNC | c.7435G>A p.D2479N | Missense Mutation (SNP) | VAF 171/422 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.643); catalogued as rs1173970601, COSV57951661; called by muse, mutect2, varscan2
- FOLH1 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57045799, COSV57046485; called by muse, mutect2, varscan2
- FOXN4 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 90/274 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.489); catalogued as COSV54498280; called by muse, mutect2, varscan2
- FRMPD3 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 147/203 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as rs1232422463, COSV52199033; called by muse, mutect2, varscan2
- FRY | c.7682C>T p.S2561L | Missense Mutation (SNP) | VAF 328/615 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs199608184; called by muse, mutect2, varscan2
- FUCA1 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 242/481 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750083315; called by muse, mutect2, varscan2
- GALNT17 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 111/392 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774457548, COSV61148627; called by muse, mutect2, varscan2
- GAS2L3 | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 154/375 reads (41%) | catalogued as rs1213751351; called by muse, mutect2, varscan2
- GCGR | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 351/488 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1280999107; called by muse, varscan2
- GIMAP7 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 118/343 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57959691; called by muse, mutect2, varscan2
- GPBP1 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99302488; called by muse, varscan2
- GPR1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 104/342 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.397); catalogued as COSV101329825; called by muse, varscan2
- GPRC5C | c.1455G>A p.W485* (on ENST00000652232; = p.W440* on NM_018653.4) | Nonsense Mutation (SNP) | VAF 179/252 reads (71%) | catalogued as rs771615403; called by muse, mutect2, varscan2
- GPRC6A | c.1708C>T p.H570Y | Missense Mutation (SNP) | VAF 123/214 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV59954910; called by muse, varscan2
- GRM3 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 102/291 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.029); catalogued as rs757078535, COSV64469272; called by muse, mutect2, varscan2
- GRXCR2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 135/240 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs447402, COSV65060697; called by muse, mutect2, varscan2
- H2BW2 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 168/231 reads (73%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as rs782625080, COSV54584150; called by muse, mutect2, varscan2
- HLA-DOA | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 220/314 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as rs753588133; called by muse, mutect2, varscan2
- HSPB3 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 147/515 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.036); catalogued as rs1266261399; called by muse, mutect2, varscan2
- HYDIN | c.6790C>T p.L2264F | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs1258354410; called by muse, varscan2
- HYDIN | c.3757C>T p.P1253S | Missense Mutation (SNP) | VAF 78/259 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs755898575; called by muse, mutect2, varscan2
- IBTK | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759848794; called by muse, mutect2, varscan2
- IDO2 | c.760G>A p.E254K (on ENST00000389060; = p.E267K on NM_194294.2) | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV58425543; called by muse, mutect2, varscan2
- IFT57 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 102/287 reads (36%) | catalogued as COSV52710984; called by muse, mutect2, varscan2
- IKBKE | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 109/305 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100898392; called by muse, mutect2, varscan2
- IQUB | c.2297G>A p.G766D | Missense Mutation (SNP) | VAF 109/347 reads (31%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1479137457, COSV61243203; called by muse, varscan2
- ITGA8 | c.2821G>A p.G941R | Missense Mutation (SNP) | VAF 114/211 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65226730, COSV65231360; called by muse, mutect2, varscan2
- ITIH5 | c.2810G>A p.G937E | Missense Mutation (SNP) | VAF 122/214 reads (57%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.062); catalogued as COSV53662725; called by muse, mutect2, varscan2
- ITSN1 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282495880; called by muse, mutect2, varscan2
- JMY | c.2158C>T p.H720Y | Missense Mutation (SNP) | VAF 229/526 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1447292056, COSV68662079; called by muse, mutect2, varscan2
- KCNA4 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 118/310 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV60255020; called by muse, varscan2
- KCNB2 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 114/329 reads (35%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.03); catalogued as COSV73052834; called by muse, mutect2, varscan2
- KCND2 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as rs984416645; called by muse, varscan2
- KCNH2 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 152/450 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV51130325; called by muse, varscan2
- KCNK18 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs552800446, COSV57971233; called by muse, mutect2
- KCNQ3 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 231/392 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs532323444, COSV66469948; called by muse, varscan2
- KIAA1210 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 145/217 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs757177547; called by muse, mutect2, varscan2
- KIF5A | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 162/427 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs199608047, COSV54052333; called by muse, mutect2, varscan2
- KIR3DL2 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1234707296; called by muse, mutect2, varscan2
- KLHDC7A | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 162/549 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as rs756338488; called by muse, varscan2
- KLK4 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 146/409 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60675929; called by muse, mutect2, varscan2
- KRT3 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 158/436 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV58816021; called by muse, varscan2
- KRT4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 98/330 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs376047865; called by muse, varscan2
- LAMA1 | c.7637C>T p.S2546F | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV67536674; called by muse, mutect2, varscan2
- LCN2 | c.276G>A p.R92= | Splice Region (SNP) | VAF 90/178 reads (51%) | catalogued as COSV52979390; called by muse, mutect2, varscan2
- LMX1A | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 123/369 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV54218228, COSV54222757; called by muse, mutect2, varscan2
- LMX1A | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768098300; called by muse, varscan2
- LOXHD1 | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 90/142 reads (63%) | SIFT tolerated (0.47); PolyPhen benign (0.096); catalogued as COSV56069718; called by muse, varscan2
- LRP1B | c.13507G>A p.D4503N | Missense Mutation (SNP) | VAF 96/352 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV67239110; called by muse, varscan2
- LRP1B | c.7011G>A p.W2337* | Nonsense Mutation (SNP) | VAF 67/204 reads (33%) | catalogued as COSV101253036; called by muse, mutect2, varscan2
- LRRC30 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 144/463 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs759621671, COSV67302386; called by muse, mutect2, varscan2
- LRRC31 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs140441511, COSV52983485; called by muse, mutect2, varscan2
- LRRC9 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1000667786, COSV54291815; called by muse, mutect2, varscan2
- LYVE1 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.566); catalogued as rs1448655715; called by muse, mutect2, varscan2
- MAGEL2 | c.2766G>A p.W922* | Nonsense Mutation (SNP) | VAF 152/398 reads (38%) | catalogued as COSV58566656; called by muse, varscan2
- MCHR2 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 220/365 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs904909725, COSV55999081, COSV56001679; called by muse, mutect2, varscan2
- MCTP1 | c.2244G>A p.V748= | Splice Region (SNP) | VAF 76/303 reads (25%) | catalogued as rs1194753370; called by muse, mutect2, varscan2
- MECOM | c.424G>A p.D142N (on ENST00000468789 / NM_001105078.4; = p.D330N on NM_004991.4) | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99244667; called by muse, varscan2
- MGA | c.2750C>T p.S917F | Missense Mutation (SNP) | VAF 100/499 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV54953026; called by muse, mutect2, varscan2
- MICALL2 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 144/360 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs765915317, COSV99875469; called by muse, varscan2
- MMP26 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 116/393 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.052); catalogued as rs1201755306, COSV56172605; called by muse, varscan2
- MOB4 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 128/341 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs376068087; called by muse, mutect2, varscan2
- MORC1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51724099, COSV51730937; called by muse, mutect2, varscan2
- MPP7 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 84/163 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.854); catalogued as COSV61732529; called by muse, mutect2, varscan2
- MRAP2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 171/287 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs574675404, COSV57635328; called by muse, varscan2
- MS4A3 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs923183715; called by muse, mutect2, varscan2
- MUC12 | c.13682C>T p.S4561L (on ENST00000379442; = p.S4418L on NM_001164462.1) | Missense Mutation (SNP) | VAF 131/1315 reads (10%) | SIFT deleterious (0); catalogued as COSV65207924; called by muse, mutect2, varscan2
- MUC12 | c.15932G>A p.G5311E (on ENST00000379442; = p.G5168E on NM_001164462.1) | Missense Mutation (SNP) | VAF 107/290 reads (37%) | SIFT tolerated (1); catalogued as COSV59331037; called by muse, varscan2
- MUC16 | c.34085C>T p.P11362L | Missense Mutation (SNP) | VAF 132/349 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV67480936; called by muse, mutect2, varscan2
- MUC16 | c.6941G>A p.G2314E | Missense Mutation (SNP) | VAF 116/340 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs267605808, COSV67446356; called by muse, varscan2
- MUC16 | c.5003G>A p.R1668K | Missense Mutation (SNP) | VAF 178/454 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as COSV67443043, COSV67456684; called by muse, varscan2
- MUC3A | c.8131C>T p.P2711S | Missense Mutation (SNP) | VAF 114/629 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.982); catalogued as COSV60226836; called by muse, mutect2, varscan2
- MYBPH | c.795G>A p.E265= | Splice Region (SNP) | VAF 98/271 reads (36%) | catalogued as rs374716725; called by muse, mutect2, varscan2
- MYO7A | c.6439G>A p.D2147N | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV60017640; called by muse, mutect2, varscan2
- NAA15 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs759209811; called by muse, mutect2, varscan2
- NBAS | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.653); catalogued as rs866659468, COSV55722010; called by muse, varscan2
- NBEA | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 106/457 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as rs267603809; called by muse, mutect2, varscan2
- NCKAP1L | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53206265; called by muse, varscan2
- NDNF | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 104/178 reads (58%) | catalogued as COSV65633669; called by muse, varscan2
- NEK11 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1389971735; called by muse, varscan2
- NELL2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs548983604, COSV61575306; called by muse, mutect2, varscan2
- NES | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 133/412 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs1484155493, COSV63961410; called by muse, mutect2, varscan2
- NEURL2 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 200/480 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1304237273; called by muse, varscan2
- NLRP11 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV64088423; called by muse, mutect2, varscan2
- NMT2 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 128/232 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs149798719; called by muse, mutect2, varscan2
- NPAP1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 136/376 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.801); catalogued as rs868115699, COSV61504054; called by muse, mutect2, varscan2
- NPAP1 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 122/352 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV61508169; called by mutect2, varscan2
- NPC1L1 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 128/390 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs370811034; called by muse, mutect2, varscan2
- NPS | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV104432609, COSV67690678; called by muse, mutect2
- NRP2 | c.2699G>A p.R900Q (on ENST00000360409 / NM_201266.2; = p.R895Q on NM_003872.3) | Missense Mutation (SNP) | VAF 148/417 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs772897853, COSV100761073; called by muse, mutect2, varscan2
- NSUN6 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs747459029; called by muse, mutect2
- NT5C1B | c.409G>A p.E137K (on ENST00000359846 / NM_001199086.2; = p.E77K on NM_033253.4) | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58398577; called by muse, varscan2
- NUTM1 | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 152/605 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV59218553; called by muse, mutect2, varscan2
- OGA | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV63382805; called by muse, mutect2, varscan2
- OR10R2 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100936814; called by muse, mutect2, varscan2
- OR13C3 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 145/274 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1564208700, COSV66166244; called by muse, mutect2, varscan2
- OR14J1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 284/391 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs199576522, COSV101012822; called by muse, varscan2
- OR2W3 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 155/429 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100831637, COSV64457032; called by muse, mutect2, varscan2
- OR4A5 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 137/382 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs368103058; called by muse, varscan2
- OR4C15 | c.938G>A p.R313Q (on ENST00000314644; = p.R259Q on NM_001001920.2) | Missense Mutation (SNP) | VAF 103/286 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); catalogued as rs149965163, COSV58952933, COSV58954574; called by muse, varscan2
- OR4C3 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 105/301 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60583951; called by muse, mutect2, varscan2
- OR4D5 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 142/392 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV58307304; called by muse, mutect2, varscan2
- OR4K17 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 135/398 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs150087607; called by muse, mutect2, varscan2
- OR4Q3 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 75/470 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs764403103, COSV59179618; called by muse, mutect2, varscan2
- OR51E1 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs867900802, COSV101211541; called by muse, mutect2, varscan2
- OR52A5 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 131/354 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs143161168; called by muse, mutect2, varscan2
- OR52B2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 172/489 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101603936; called by muse, mutect2, varscan2
- OR52E8 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs781170349, COSV66205287; called by muse, mutect2, varscan2
- OR5M8 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 128/357 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV59115844; called by muse, varscan2
- OR6C4 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV67793117; called by muse, mutect2, varscan2
- OR6T1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 135/395 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868745413, COSV58306274, COSV58307592; called by muse, varscan2
- OR8B4 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 141/375 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); catalogued as rs758603752; called by muse, mutect2, varscan2
- PAK3 | c.398C>T p.A133V (on ENST00000262836 / NM_001324328.2; = p.A118V on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/195 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV53270240; called by muse, varscan2
- PAPPA | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 131/264 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs765817253; called by muse, varscan2
- PAPPA2 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 129/376 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as rs550436411, COSV62774677; called by muse, mutect2, varscan2
- PBRM1 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 144/338 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs1283107190; called by muse, mutect2, varscan2
- PCDH15 | c.4621G>A p.E1541K (on ENST00000644397 / NM_001354429.2; = p.E1490K on NM_001142769.3) | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV64728762; called by muse, mutect2
- PCDHA4 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 172/319 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs532147064, COSV63539710; called by muse, mutect2, varscan2
- PCDHB10 | c.1220G>A p.G407D | Missense Mutation (SNP) | VAF 117/237 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.284); catalogued as rs781930141; called by muse, mutect2, varscan2
- PCDHB6 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 210/410 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs782123595, COSV50693258; called by muse, varscan2
- PCDHGB7 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 156/270 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs563445438, COSV53979344; called by muse, varscan2
- PCK1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60128830, COSV60130646; called by muse, mutect2, varscan2
- PCLO | c.11191G>A p.E3731K | Missense Mutation (SNP) | VAF 160/414 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1437780637, COSV100431943; called by muse, mutect2, varscan2
- PCLO | c.9058G>A p.D3020N | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV61621978; called by muse, varscan2
- PCLO | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV61617434; called by muse, mutect2, varscan2
- PCNX2 | c.4333C>T p.R1445* | Nonsense Mutation (SNP) | VAF 84/260 reads (32%) | catalogued as rs754419529, COSV50782807; called by muse, varscan2
- PCNX2 | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 112/352 reads (32%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); catalogued as rs1379312512; called by muse, varscan2
- PCSK5 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 90/185 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs768708216, COSV65085674; called by muse, mutect2, varscan2
- PDE6C | c.1737G>A p.M579I | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs1454882369; called by muse, mutect2
- PDE7B | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 100/180 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57493741; called by muse, varscan2
- PDE8B | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 128/310 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53736862; called by muse, varscan2
- PER2 | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 194/519 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.027); catalogued as COSV54524080; called by muse, mutect2, varscan2
- PIK3CG | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 140/432 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100783275; called by muse, varscan2
- PLCB1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs867281730, COSV62042382; called by muse, varscan2
- PLXNB3 | c.3931G>A p.D1311N | Missense Mutation (SNP) | VAF 161/223 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62795400; called by muse, mutect2, varscan2
- PMS2 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 97/300 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV99763911; called by muse, mutect2, varscan2
- POLR1G | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 118/368 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as rs1471669477; called by muse, mutect2, varscan2
- POTEJ | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 180/398 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.855); catalogued as rs1180786734; called by muse, varscan2
- PPP1R12A | c.2156C>T p.T719I | Missense Mutation (SNP) | VAF 100/308 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.585); catalogued as rs778776432; called by muse, mutect2, varscan2
- PRAMEF20 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs202075096; called by muse, mutect2, varscan2
- PRICKLE1 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 80/313 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1306531699, COSV61543783; called by muse, varscan2
- PTPRB | c.1649G>A p.G550E | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs865990448, COSV54254990; called by muse, mutect2, varscan2
- PXDNL | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV62492962, COSV62495546; called by muse, mutect2, varscan2
- PZP | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.506); catalogued as rs894110497, COSV54362187; called by muse, mutect2, varscan2
- RAB4B | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1419905679; called by muse, varscan2
- RAD54L2 | c.3974C>T p.S1325F | Missense Mutation (SNP) | VAF 169/487 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs746698421; called by muse, mutect2, varscan2
- RAI2 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 160/216 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1228495373, COSV104403939; called by muse, varscan2
- RAPGEF5 | c.490G>A p.E164K (on ENST00000401957 / NM_001367602.2; = p.E467K on NM_012294.5) | Missense Mutation (SNP) | VAF 124/412 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV59783449; called by muse, mutect2
- RBMX | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 95/138 reads (69%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV57809051; called by muse, mutect2, varscan2
- RBP3 | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 148/279 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.129); catalogued as rs782295621; called by muse, varscan2
- RBSN | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 142/406 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs753817033, COSV53791598; called by muse, mutect2, varscan2
- RELN | c.7669G>A p.G2557S | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as rs560581732; called by muse, mutect2, varscan2
- RGPD2 | c.4156C>T p.R1386C | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759292559; called by muse, mutect2, varscan2
- RGS17 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 71/138 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as rs781400978, COSV52806897; called by muse, varscan2
- RGS22 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 180/295 reads (61%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1286552386, COSV62664162; called by muse, varscan2
- RGS9 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 204/274 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV99287243; called by muse, mutect2, varscan2
- RNF170 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 27/232 reads (12%) | catalogued as rs764459425, COSV99533934; called by muse, mutect2, varscan2
- RNF31 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 126/432 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV53759545; called by muse, varscan2
- ROBO4 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 110/367 reads (30%) | catalogued as rs1460744832; called by muse, varscan2
- RUNX1T1 | c.500C>T p.S167F (on ENST00000265814 / NM_001198628.1; = p.S140F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as rs760524107, COSV56138314, COSV99750977; called by muse, varscan2
- RXFP2 | c.1724C>A p.P575Q | Missense Mutation (SNP) | VAF 76/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53634299, COSV53636875; called by muse, mutect2, varscan2
- RXFP2 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV53635903; called by muse, mutect2, varscan2
- RYR2 | c.12409G>A p.E4137K | Missense Mutation (SNP) | VAF 139/388 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598439, COSV63666259; called by muse, mutect2, varscan2
- SBK2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 126/431 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as rs202103094; called by muse, mutect2, varscan2
- SCAF1 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 112/293 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.075); catalogued as rs1332820528; called by muse, mutect2, varscan2
- SCAP | c.2321G>A p.G774D | Missense Mutation (SNP) | VAF 110/350 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867962723, COSV55547696; called by muse, mutect2, varscan2
- SCN3A | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 153/431 reads (35%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.734); catalogued as COSV51812047; called by muse, mutect2, varscan2
- SCN9A | c.5104G>A p.G1702R (on ENST00000303354; = p.G1691R on NM_002977.3) | Missense Mutation (SNP) | VAF 100/377 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs267598971; called by muse, mutect2, varscan2
- SDC3 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 136/426 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV100232168; called by muse, mutect2, varscan2
- SDE2 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 81/239 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs771107418, COSV55253062; called by muse, mutect2, varscan2
- SETD5 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs1315341489; called by muse, mutect2, varscan2
- SEZ6 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 111/479 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs1460124338; called by muse, mutect2, varscan2
- SH3GLB1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778164999, COSV65280148, COSV65280805; called by muse, mutect2, varscan2
- SHROOM3 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 153/275 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs866701391; called by muse, mutect2, varscan2
- SI | c.5314C>T p.L1772F | Missense Mutation (SNP) | VAF 111/313 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100016441; called by muse, mutect2, varscan2
- SIGLEC5 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 125/380 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs776039619; called by muse, mutect2, varscan2
- SIN3A | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 205/387 reads (53%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs543871480; called by muse, varscan2
- SLAMF6 | c.678G>A p.M226I | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.177); catalogued as rs1237999809; called by muse, mutect2, varscan2
- SLC17A4 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as rs774010672; called by muse, mutect2, varscan2
- SLC1A7 | c.293G>A p.W98* | Nonsense Mutation (SNP) | VAF 143/273 reads (52%) | catalogued as rs1426995720; called by muse, mutect2, varscan2
- SLC30A10 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 119/345 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63071406; called by muse, mutect2, varscan2
- SLC39A12 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.662); catalogued as COSV66196721; called by muse, mutect2, varscan2
- SLC4A8 | c.2041G>A p.G681R | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60657101; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1910C>T p.S637L (on ENST00000540229 / NM_001371097.1; = p.S576L on NM_001009562.4) | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV67444158; called by muse, mutect2, varscan2
- SLITRK3 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 128/357 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1288411873; called by muse, mutect2, varscan2
- SLTM | c.2749C>T p.P917S | Missense Mutation (SNP) | VAF 114/436 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.388); catalogued as rs201656241, COSV65848805; called by muse, varscan2
- SOGA3 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 100/194 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64106658; called by muse, mutect2, varscan2
- SORCS3 | c.2291G>A p.S764N | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV63795881, COSV63797138; called by muse, mutect2
- SPATA17 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV65119512; called by muse, varscan2
- SPATA48 | c.1010T>C p.V337A | Missense Mutation (SNP) | VAF 106/340 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs773994050; called by muse, mutect2
- SPHKAP | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 130/340 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV60872577; called by muse, mutect2, varscan2
- SPIC | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV54691128; called by muse, mutect2, varscan2
- ST8SIA2 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 148/591 reads (25%) | PolyPhen benign (0.402); catalogued as rs1178365935; called by muse, mutect2, varscan2
- STARD13 | c.380G>A p.R127K (on ENST00000336934 / NM_001243476.3; = p.R9K on NM_052851.3) | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs757599182, COSV55229512; called by muse, mutect2, varscan2
- STEAP4 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 116/372 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57328022; called by muse, varscan2
- SYT2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66143039; called by muse, mutect2, varscan2
- SYT9 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 114/360 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as COSV59624080; called by muse, varscan2
- TAF1L | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 150/287 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54268961; called by muse, mutect2, varscan2
- TAGLN3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 113/323 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1372306970; called by muse, mutect2, varscan2
- TAS2R60 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV100223495, COSV60329939; called by muse, varscan2
- TAT | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100587653; called by muse, mutect2, varscan2
- TBC1D4 | c.2332C>T p.L778F | Missense Mutation (SNP) | VAF 129/541 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372388426; called by muse, mutect2, varscan2
- TBX5 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 152/420 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1426492228, COSV59858496; called by muse, varscan2
- TDRD9 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 147/438 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV59144799; called by muse, mutect2, varscan2
- TENM1 | c.4768C>T p.R1590C | Missense Mutation (SNP) | VAF 202/288 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64444357; called by muse, varscan2
- TEP1 | c.7397C>T p.S2466L | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs768609519, COSV52992298; called by muse, mutect2, varscan2
- TET2 | c.3781C>T p.R1261C | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs898441677, COSV54397005, COSV54424071, COSV99485797; called by muse, mutect2, varscan2
- TET3 | c.4421C>T p.S1474F | Missense Mutation (SNP) | VAF 138/476 reads (29%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.593); catalogued as rs1030846816, COSV69642799; called by muse, mutect2, varscan2
- TEX15 | c.4510G>A p.E1504K (on ENST00000256246; = p.E1887K on NM_001350162.2) | Missense Mutation (SNP) | VAF 99/202 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as rs1033208856; called by muse, mutect2, varscan2
- THAP7 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 150/460 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1355360528; called by muse, mutect2, varscan2
- THEMIS | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 151/249 reads (61%) | SIFT tolerated (0.95); PolyPhen benign (0.048); catalogued as COSV64072232; called by muse, mutect2, varscan2
- TM4SF4 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1293337765, COSV59514955; called by muse, mutect2, varscan2
- TMEM68 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs772631105; called by muse, varscan2
- TNR | c.3283C>T p.R1095* | Nonsense Mutation (SNP) | VAF 109/299 reads (36%) | catalogued as rs1238381479, COSV54878899, COSV54910805; called by muse, varscan2
- TOX2 | c.1205C>T p.P402L (on ENST00000358131 / NM_001098798.2; = p.P378L on NM_032883.3) | Missense Mutation (SNP) | VAF 146/565 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100364960; called by muse, varscan2
- TPRG1 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 158/433 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1296603015; called by muse, mutect2, varscan2
- TRBV30 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs782049322; called by muse, mutect2, varscan2
- TRIM42 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 135/401 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as rs200221279, COSV53880710; called by muse, mutect2, varscan2
- TRIM69 | c.1331G>A p.G444D (on ENST00000329464 / NM_182985.5; = p.G285D on NM_080745.5) | Missense Mutation (SNP) | VAF 142/599 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57802944; called by muse, varscan2
- TSHZ2 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 136/425 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61589657; called by muse, mutect2, varscan2
- TTLL13P | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 89/430 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.177); catalogued as COSV100296361, COSV60036444; called by muse, mutect2, varscan2
- TTLL2 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 149/261 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53442490, COSV53442709; called by muse, mutect2, varscan2
- TTN | c.18212T>C p.V6071A (on ENST00000591111; = p.V5144A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/253 reads (38%) | PolyPhen benign (0.033); catalogued as COSV100630359; called by muse, mutect2, varscan2
- TTN | c.6275G>A p.G2092E (on ENST00000591111; = p.G2046E on NM_003319.4) | Missense Mutation (SNP) | VAF 134/412 reads (33%) | PolyPhen possibly damaging (0.714); catalogued as COSV59887856; called by muse, varscan2
- UMOD | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 117/371 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100208246, COSV56777291; called by muse, mutect2, varscan2
- UNC13C | c.3961G>A p.G1321R | Missense Mutation (SNP) | VAF 69/359 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52891397; called by muse, mutect2, varscan2
- USH1C | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 77/236 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50016345; called by muse, mutect2, varscan2
- USP29 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 56/215 reads (26%) | catalogued as COSV54238960; called by muse, mutect2, varscan2
- USP54 | c.3715C>T p.Q1239* | Nonsense Mutation (SNP) | VAF 20/320 reads (6%) | catalogued as COSV100357502; called by muse, mutect2
- USP6NL | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 31/408 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1362506945, COSV99509499; called by muse, mutect2
- VPS13B | c.3346C>T p.L1116F | Missense Mutation (SNP) | VAF 188/294 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV100661679; called by muse, varscan2
- VPS50 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as COSV59916130; called by muse, mutect2, varscan2
- WDR17 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV54583744; called by muse, mutect2, varscan2
- WDR49 | c.1213G>A p.D405N (on ENST00000308378 / NM_001366158.1; = p.D746N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/316 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57704933; called by muse, mutect2, varscan2
- WDR49 | c.847C>T p.H283Y (on ENST00000308378 / NM_001366158.1; = p.H624Y on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100393545, COSV57716115; called by muse, mutect2, varscan2
- WDR87 | c.4228G>A p.E1410K | Missense Mutation (SNP) | VAF 111/349 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.192); catalogued as COSV58194878; called by muse, mutect2, varscan2
- WFDC5 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 133/463 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.106); catalogued as rs141103884; called by muse, mutect2, varscan2
- ZBBX | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56782473; called by muse, mutect2, varscan2
- ZBED9 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 298/411 reads (73%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV101509090; called by muse, varscan2
- ZBTB39 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 158/405 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV55628053; called by muse, mutect2, varscan2
- ZC3H7A | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 105/357 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as rs779684309, COSV100865550; called by muse, mutect2, varscan2
- ZFPM2 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101023152; called by muse, mutect2
- ZNF329 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 128/408 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs755020594, COSV100798677; called by muse, mutect2, varscan2
- ZNF385A | c.224C>T p.S75F (on ENST00000338010 / NM_001130967.3; = p.S55F on NM_015481.3) | Missense Mutation (SNP) | VAF 113/330 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61492681; called by muse, mutect2, varscan2
- ZNF385B | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 144/444 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69800924; called by muse, mutect2, varscan2
- ZNF440 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); catalogued as COSV100407287; called by muse, mutect2, varscan2
- ZNF485 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.425); catalogued as COSV62423708; called by muse, mutect2
- ZNF585B | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 123/399 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs368332359; called by muse, mutect2, varscan2
- ZNF721 | c.2035C>T p.H679Y (on ENST00000338977; = p.H691Y on NM_133474.4) | Missense Mutation (SNP) | VAF 258/391 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs782152954, COSV59094425; called by muse, varscan2
- ZNF846 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 128/414 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as rs765545468, COSV101194409; called by muse, mutect2, varscan2
- ZNF99 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs750390040, COSV68056719; called by muse, mutect2, varscan2
- ZSCAN4 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 161/462 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs867400751; called by muse, mutect2, varscan2
- AACS | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 124/361 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCA13 | c.7055A>T p.Y2352F | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ABCB1 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- AC005833.1 | c.996G>T p.L332F | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACTC1 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 80/444 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ADAD1 | c.1381T>G p.Y461D | Missense Mutation (SNP) | VAF 103/200 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ADAM2 | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 114/279 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAM23 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, varscan2
- ADAM28 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADCY8 | c.2977G>A p.D993N | Missense Mutation (SNP) | VAF 209/377 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ADGRF5 | c.3309G>A p.W1103* | Nonsense Mutation (SNP) | VAF 136/404 reads (34%) | called by muse, mutect2, varscan2
- AJM1 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.182); called by muse, varscan2
- AKR1C1 | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 97/173 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- AKR1C1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ALOX12B | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 157/265 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.052); called by muse, varscan2
- ANKEF1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- ANKFN1 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 106/166 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- ANKRD31 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 116/248 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ANKRD50 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 132/254 reads (52%) | called by muse, mutect2, varscan2
- AP3B1 | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 129/294 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AP3B2 | c.3000del p.I1001Sfs*21 (on ENST00000261722; = p.I995Sfs*21 on NM_004644.5) | Frame Shift Del (DEL) | VAF 69/430 reads (16%) | called by mutect2, pindel, varscan2
- APOL6 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 127/344 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- AQP9 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 110/402 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ARHGEF28 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 53/224 reads (24%) | called by muse, mutect2, varscan2
- ARPP21 | c.2182-1G>A p.X728_splice | Splice Site (SNP) | VAF 91/221 reads (41%) | called by muse, mutect2, varscan2
- ASTN2 | c.1891G>A p.E631K (on ENST00000313400 / NM_001365069.1; = p.E580K on NM_014010.5) | Missense Mutation (SNP) | VAF 80/144 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.223); called by muse, varscan2
- ATF4 | c.1010T>C p.L337S | Missense Mutation (SNP) | VAF 126/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- ATP13A5 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, varscan2
- ATP1A4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ATP8A1 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 109/157 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATR | c.2927C>T p.S976F | Missense Mutation (SNP) | VAF 111/388 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.055); called by muse, varscan2
- BHMG1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 171/479 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BTNL8 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 147/260 reads (57%) | SIFT tolerated (0.84); PolyPhen benign (0.046); called by muse, varscan2
- C12orf43 | c.450C>T p.S150= | Splice Region (SNP) | VAF 109/310 reads (35%) | called by muse, mutect2, varscan2
- C1orf232 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.981); called by muse, varscan2
- C20orf194 | c.1858C>T p.H620Y | Missense Mutation (SNP) | VAF 160/536 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- C2CD4D | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 140/430 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); called by muse, varscan2
- C6 | c.176A>C p.N59T | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- C9 | c.328+1G>A p.X110_splice | Splice Site (SNP) | VAF 95/274 reads (35%) | called by muse, mutect2, varscan2
- CA10 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 263/392 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CACNA2D3 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CACNA2D3 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 108/346 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CALHM5 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 126/242 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CASP12 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.549); called by muse, varscan2
- CCBE1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 95/186 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CCDC175 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CCDC186 | c.1213T>G p.S405A | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.011); called by muse, mutect2
- CCDC73 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CDH7 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CDH9 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, varscan2
- CDIPT | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 114/307 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, varscan2
- CEACAM20 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 120/334 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- CEL | c.1276C>T p.Q426* (on ENST00000673714; = p.Q423* on NM_001807.6) | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- CFAP43 | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CFAP54 | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CFAP57 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 93/294 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CHAF1B | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 154/517 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD7 | c.4087C>T p.L1363F | Missense Mutation (SNP) | VAF 100/353 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRDL2 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 121/338 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CHST9 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 96/178 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CIITA | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 124/406 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, varscan2
- CIT | c.4417T>A p.S1473T | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CLDN19 | c.86A>C p.Q29P | Missense Mutation (SNP) | VAF 167/443 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CLEC2L | c.467G>A p.W156* | Nonsense Mutation (SNP) | VAF 108/338 reads (32%) | called by muse, mutect2, varscan2
- CMYA5 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 103/396 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CNTN3 | c.2684A>T p.N895I | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- COBLL1 | c.2479G>A p.E827K (on ENST00000392717; = p.E789K on NM_014900.5) | Missense Mutation (SNP) | VAF 130/327 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- COL12A1 | c.3517_3526del p.E1173Pfs*43 | Frame Shift Del (DEL) | VAF 62/238 reads (26%) | called by mutect2, pindel, varscan2
- COL6A2 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 93/343 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COPB1 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPS7A | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 107/334 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CRYBG2 | c.1538A>T p.E513V | Missense Mutation (SNP) | VAF 99/468 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CSF1R | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 87/161 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- CSF2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 110/190 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- CTBP2 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.305); called by muse, mutect2
- CTSV | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 58/90 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CX3CR1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 127/388 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP27C1 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, varscan2
- CYP27C1 | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 76/243 reads (31%) | called by muse, varscan2
- CYP3A7 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP46A1 | c.981-1G>A p.X327_splice | Splice Site (SNP) | VAF 95/299 reads (32%) | called by muse, mutect2, varscan2
- DCAF12 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 86/138 reads (62%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); called by muse, varscan2
- DCAF15 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 134/398 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.05); called by muse, varscan2
- DNAH11 | c.7601C>T p.S2534F | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- DNAH12 | c.8231C>T p.P2744L (on ENST00000351747; = p.P3612L on NM_001366028.2) | Missense Mutation (SNP) | VAF 85/284 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- DNAJC12 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2
- DNM3 | c.1571A>G p.Q524R | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, varscan2
- DOCK3 | c.2540C>T p.S847F | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DPPA3 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DPY30 | c.107T>A p.I36N | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EBF2 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDIL3 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 213/478 reads (45%) | called by muse, mutect2, varscan2
- EFCAB6 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 110/268 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, varscan2
- EFHC2 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 73/104 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, varscan2
- EIF3D | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.038); called by muse, varscan2
- EIF4A1 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 98/188 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, varscan2
- ELMO2 | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 127/423 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EML6 | c.4964G>A p.G1655E | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ERICH6 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.26); called by muse, varscan2
- F5 | c.3133C>T p.P1045S | Missense Mutation (SNP) | VAF 163/467 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FAM160B1 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- FAM167B | c.459G>A p.M153I | Missense Mutation (SNP) | VAF 226/535 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAM71E2 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, varscan2
- FBLN2 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 121/290 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FCRL1 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FLG | c.5044G>A p.G1682R | Missense Mutation (SNP) | VAF 156/447 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FLI1 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 148/422 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, varscan2
- FLI1 | c.1268G>A p.W423* | Nonsense Mutation (SNP) | VAF 117/388 reads (30%) | called by muse, mutect2, varscan2
- FLI1 | c.1269G>A p.W423* | Nonsense Mutation (SNP) | VAF 107/364 reads (29%) | called by muse, varscan2
- FMO2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FREM2 | c.5740T>A p.L1914M | Missense Mutation (SNP) | VAF 81/430 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- FREM2 | c.5741T>A p.L1914* | Nonsense Mutation (SNP) | VAF 81/428 reads (19%) | called by muse, mutect2, varscan2
- FSIP2 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GATA4 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GCN1 | c.5908G>A p.E1970K | Missense Mutation (SNP) | VAF 120/377 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GJD2 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 186/701 reads (27%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.972); called by muse, mutect2
- GOLGA8F | c.262G>A p.E88K (on ENST00000526619; = p.E294K on NM_001350920.2) | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.741); called by muse, mutect2
- GOLGA8J | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 78/278 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- GPA33 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPR162 | c.1133G>A p.G378E (on ENST00000311268 / NM_019858.2; = p.G94E on NM_014449.2) | Missense Mutation (SNP) | VAF 152/429 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.074); called by muse, varscan2
- GPR33 | c.599G>A p.W200* | Nonsense Mutation (SNP) | VAF 149/441 reads (34%) | called by muse, mutect2, varscan2
- GPR55 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 152/445 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRHL2 | c.863G>A p.C288Y | Missense Mutation (SNP) | VAF 166/280 reads (59%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.793); called by mutect2, varscan2
- GRIA3 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 118/150 reads (79%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.566); called by muse, varscan2
- GRM1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 124/236 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- H1-7 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 185/488 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HAPLN4 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 139/352 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); called by muse, varscan2
- HELQ | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 137/227 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HERC2 | c.14356C>T p.H4786Y | Missense Mutation (SNP) | VAF 208/597 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- HMGCS2 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 80/445 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.057); called by muse, varscan2
- HP1BP3 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); called by muse, varscan2
- HS6ST3 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 287/547 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HYDIN | c.7777G>A p.G2593R | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- IDE | c.511T>G p.C171G | Missense Mutation (SNP) | VAF 115/204 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IGHG3 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ILF3 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INO80 | c.4472C>T p.P1491L | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- INO80 | c.4471C>T p.P1491S | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- IRAG1 | c.1746C>T p.S582= | Splice Region (SNP) | VAF 62/181 reads (34%) | called by muse, mutect2, varscan2
- KALRN | c.3895G>A p.D1299N | Missense Mutation (SNP) | VAF 96/364 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KANK4 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 105/202 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KCNAB1 | c.316C>T p.L106F (on ENST00000490337 / NM_172160.3; = p.L95F on NM_003471.3) | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); called by muse, varscan2
- KCNB2 | c.187A>T p.K63* | Nonsense Mutation (SNP) | VAF 116/400 reads (29%) | called by mutect2, varscan2
- KCNB2 | c.2287C>A p.Q763K | Missense Mutation (SNP) | VAF 135/357 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.013); called by muse, varscan2
- KCNG3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 200/531 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNN1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 185/539 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.04); called by muse, varscan2
- KIF11 | c.2123C>T p.T708I | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2
- KLHDC4 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 126/316 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- KMT2D | c.16406C>T p.P5469L | Missense Mutation (SNP) | VAF 92/313 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); called by muse, varscan2
- KMT2D | c.6830C>T p.P2277L | Missense Mutation (SNP) | VAF 172/462 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, varscan2
- LAMA3 | c.3071G>A p.G1024E | Missense Mutation (SNP) | VAF 104/200 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, varscan2
- LAMB2 | c.3728G>A p.G1243D | Missense Mutation (SNP) | VAF 127/394 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMTOR4 | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 127/327 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LDLR | c.2335G>A p.G779R | Missense Mutation (SNP) | VAF 116/366 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, varscan2
- LELP1 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LEMD3 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 164/504 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LILRA1 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 133/426 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, varscan2
- LIPI | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LMNTD2 | c.124C>T p.H42Y | Missense Mutation (SNP) | VAF 182/456 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- LMOD1 | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 142/402 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- LMTK2 | c.3404C>T p.P1135L | Missense Mutation (SNP) | VAF 146/423 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LOXL2 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- LRP1B | c.5200G>A p.E1734K | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LUZP2 | c.397-1G>A p.X133_splice | Splice Site (SNP) | VAF 63/216 reads (29%) | called by muse, varscan2
- MAGEB1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 197/288 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- MAOB | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 123/178 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); called by muse, varscan2
- MASP2 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- MDM2 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MGAM2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- MMP10 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- MMP25 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 160/418 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MORN1 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 131/460 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MRC1 | c.2558G>A p.R853K | Missense Mutation (SNP) | VAF 108/184 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRC2 | c.966G>A p.W322* | Nonsense Mutation (SNP) | VAF 167/238 reads (70%) | called by muse, mutect2, varscan2
- MROH2A | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL32 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 112/367 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A6A | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MTMR7 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.041); called by muse, varscan2
- MYH6 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- MYO3B | c.2992C>T p.L998F | Missense Mutation (SNP) | VAF 97/274 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NBEAL1 | c.1777dup p.S593Ffs*19 | Frame Shift Ins (INS) | VAF 97/354 reads (27%) | called by pindel, varscan2
- NDUFA12 | c.85A>C p.R29= | Splice Region (SNP) | VAF 84/256 reads (33%) | called by muse, varscan2
- NKX1-2 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 128/266 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, varscan2
- NLRC5 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 109/346 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, varscan2
- NLRP11 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 87/308 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NLRP5 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP8 | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 120/380 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOTCH2 | c.5258G>A p.G1753E | Missense Mutation (SNP) | VAF 89/582 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRAP | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- NTM | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.101); called by muse, varscan2
- NUP98 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 118/386 reads (31%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OAZ2 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 115/472 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10J5 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- OR11H2 | c.420G>A p.M140I (on ENST00000556246; = p.M151I on NM_001197287.1) | Missense Mutation (SNP) | VAF 116/656 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- OR1N1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 128/227 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2T8 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- OR4A8 | c.411G>C p.Q137H | Missense Mutation (SNP) | VAF 106/278 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- OR4A8 | c.754T>G p.C252G | Missense Mutation (SNP) | VAF 105/304 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4D5 | c.482C>A p.A161E | Missense Mutation (SNP) | VAF 143/408 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- OR4E2 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- OR4F21 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 165/471 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- OR4K3 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 85/540 reads (16%) | called by muse, mutect2, varscan2
- OR51B6 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 149/400 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2
- OR52A5 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 98/304 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.651); called by muse, varscan2
- OR6K6 | c.688C>T p.H230Y (on ENST00000368144; = p.H206Y on NM_001005184.1) | Missense Mutation (SNP) | VAF 146/435 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6Q1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 145/409 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- OTOGL | c.2537G>A p.G846E (on ENST00000547103; = p.G837E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- OTUD3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 147/334 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- P4HA3 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 100/303 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PADI4 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 122/409 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, varscan2
- PANX2 | c.62T>G p.L21R | Missense Mutation (SNP) | VAF 151/396 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PARD3B | c.2978G>A p.R993K (on ENST00000406610 / NM_001302769.2; = p.R924K on NM_057177.7) | Missense Mutation (SNP) | VAF 106/342 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARVB | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 125/362 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PCARE | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 115/379 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH11Y | c.2125C>T p.P709S (on ENST00000400457 / NM_032973.2; = p.P698S on NM_032971.3) | Missense Mutation (SNP) | VAF 160/232 reads (69%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, varscan2
- PCDH11Y | c.2126C>T p.P709L (on ENST00000400457 / NM_032973.2; = p.P698L on NM_032971.3) | Missense Mutation (SNP) | VAF 159/229 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, varscan2
- PCDH8 | c.2957C>T p.T986I | Missense Mutation (SNP) | VAF 151/559 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, varscan2
- PCDHB13 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 200/436 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); called by muse, varscan2
- PCDHB8 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 119/593 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- PCNX2 | c.5200G>A p.A1734T | Missense Mutation (SNP) | VAF 141/374 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, varscan2
- PDCD11 | c.3535C>T p.P1179S | Missense Mutation (SNP) | VAF 111/211 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- PDE6A | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 88/159 reads (55%) | called by muse, mutect2, varscan2
- PDGFRA | c.2154G>A p.R718= | Splice Region (SNP) | VAF 96/174 reads (55%) | called by muse, varscan2
- PHACTR2 | c.1702C>A p.L568I | Missense Mutation (SNP) | VAF 107/165 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- PHF21A | c.1631C>T p.P544L (on ENST00000418153 / NM_001101802.3; = p.P498L on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PIAS1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 127/414 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIK3C3 | c.787-1G>A p.X263_splice | Splice Site (SNP) | VAF 74/153 reads (48%) | called by muse, mutect2, varscan2
- PIWIL2 | c.2107A>G p.T703A | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PKD1L3 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PLA2G7 | c.894G>A p.W298* | Nonsense Mutation (SNP) | VAF 212/272 reads (78%) | called by muse, mutect2, varscan2
- PLA2R1 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PLCL2 | c.758G>A p.G253E (on ENST00000615277 / NM_001144382.2; = p.G127E on NM_015184.5) | Missense Mutation (SNP) | VAF 114/307 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- POTEI | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- PPM1E | c.2144G>A p.R715K | Missense Mutation (SNP) | VAF 311/435 reads (71%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP4R4 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- PRAG1 | c.3520C>T p.P1174S | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRAMEF14 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 92/307 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRAMEF18 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 220/1052 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); called by muse, varscan2
- PSG2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PTBP1 | c.38A>T p.K13M | Missense Mutation (SNP) | VAF 106/338 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, varscan2
- PTBP1 | c.1082A>C p.Y361S (on ENST00000349038 / NM_031991.4; = p.Y387S on NM_002819.5) | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PTBP1 | c.1376C>T p.S459F (on ENST00000349038 / NM_031991.4; = p.S485F on NM_002819.5) | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN6 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 112/291 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRF | c.5543T>G p.V1848G | Missense Mutation (SNP) | VAF 119/366 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRO | c.971A>C p.N324T | Missense Mutation (SNP) | VAF 143/413 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PUM1 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 104/199 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PWWP2B | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 23/435 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.392); called by muse, mutect2
- RBKS | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- RBL1 | c.3194G>C p.R1065T | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RDH12 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 101/312 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, varscan2
- REP15 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 105/258 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- RHCG | c.1239G>A p.G413= | Splice Region (SNP) | VAF 47/255 reads (18%) | called by muse, varscan2
- RIN2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 83/146 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- RNF20 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 114/217 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, varscan2
- ROBO3 | c.3572C>T p.S1191F | Missense Mutation (SNP) | VAF 146/396 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- RPL39L | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 137/420 reads (33%) | called by muse, mutect2, varscan2
- RSBN1 | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 108/187 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- RTL1 | c.2291C>T p.S764F | Missense Mutation (SNP) | VAF 114/346 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, varscan2
- RYR3 | c.4135C>T p.H1379Y | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- SAMD11 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 236/550 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.415); called by mutect2, varscan2
- SATB1 | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SBSN | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 140/440 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCART1 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 90/162 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SEMA3G | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 109/337 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- SEMA5A | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 128/444 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); called by muse, varscan2
- SERPINA12 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, varscan2
- SERPINA5 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 130/422 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SIRPB1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 114/685 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC12A3 | c.2849G>A p.R950K (on ENST00000563236 / NM_001126108.2; = p.R959K on NM_000339.3) | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC15A5 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC16A7 | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 119/321 reads (37%) | called by muse, mutect2, varscan2
- SLC17A4 | c.826-1G>A p.X276_splice | Splice Site (SNP) | VAF 92/238 reads (39%) | called by muse, mutect2, varscan2
- SLC17A8 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.211); called by muse, varscan2
- SLC25A20 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 115/322 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC25A20 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 115/320 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, varscan2
- SLC44A5 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 89/182 reads (49%) | called by muse, mutect2, varscan2
- SLC5A12 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 93/287 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- SLCO3A1 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SLCO6A1 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 126/399 reads (32%) | called by muse, mutect2, varscan2
- SMARCC2 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 122/356 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SMC3 | c.2427G>A p.Q809= | Splice Region (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- SORBS1 | c.3089C>T p.S1030F | Missense Mutation (SNP) | VAF 134/264 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, varscan2
- SPHKAP | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 130/405 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPON1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 90/294 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SRD5A1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRGAP1 | c.2657C>T p.S886F | Missense Mutation (SNP) | VAF 173/435 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- SRGAP3 | c.1771C>T p.L591F | Missense Mutation (SNP) | VAF 107/310 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ST3GAL1 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 25/311 reads (8%) | PolyPhen benign (0.013); called by muse, mutect2
- ST6GALNAC3 | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 104/213 reads (49%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAB2 | c.7290G>A p.W2430* | Nonsense Mutation (SNP) | VAF 116/350 reads (33%) | called by muse, mutect2, varscan2
- STARD9 | c.5222C>T p.P1741L | Missense Mutation (SNP) | VAF 112/498 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.537); called by muse, varscan2
- SUGP1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 141/392 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SULT1C4 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- SUPT20H | c.319G>A p.E107K (on ENST00000350612 / NM_001014286.3; = p.E108K on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/371 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SVEP1 | c.5296G>A p.G1766R | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SYCP2 | c.3407C>T p.S1136F | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); called by muse, varscan2
- SYT2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.672); called by muse, varscan2
- SYTL1 | c.1421A>T p.N474I (on ENST00000543823; = p.N462I on NM_032872.3) | Missense Mutation (SNP) | VAF 180/566 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAAR6 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 108/184 reads (59%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TAF11L13 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 121/504 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- TALDO1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 140/368 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TAS2R16 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 123/356 reads (35%) | called by muse, mutect2, varscan2
- TAT | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBRG1 | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 134/400 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TCTEX1D4 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 176/548 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- TDGF1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TDRD1 | c.2746C>T p.Q916* | Nonsense Mutation (SNP) | VAF 64/134 reads (48%) | called by muse, varscan2
- TDRKH | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 133/383 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, varscan2
- TECPR2 | c.3317-1G>A p.X1106_splice | Splice Site (SNP) | VAF 87/241 reads (36%) | called by muse, mutect2, varscan2
- TET3 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 157/470 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TEX15 | c.1090G>A p.E364K (on ENST00000256246; = p.E747K on NM_001350162.2) | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); called by muse, varscan2
- TEX37 | c.375G>T p.Q125H | Missense Mutation (SNP) | VAF 24/637 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.35); called by muse, mutect2
- TGM7 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 98/371 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.307); called by muse, varscan2
- THRSP | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 136/410 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, varscan2
- TIMELESS | c.2426C>T p.S809F | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, varscan2
- TLR1 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 244/348 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- TM6SF1 | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 89/372 reads (24%) | called by muse, mutect2, varscan2
- TMEM108 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 136/441 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, varscan2
- TMEM132D | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 113/336 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.039); called by muse, varscan2
- TMEM185B | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 154/444 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TOX3 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPST1 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TRA2A | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 98/307 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, varscan2
- TRANK1 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 122/440 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, varscan2
- TRAV12-3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 115/359 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- TRBV28 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- TRBV7-1 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- TRIM49C | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRIM64C | c.327G>C p.L109F | Missense Mutation (SNP) | VAF 115/404 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRPC5 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 172/243 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TRPC6 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TSPEAR | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 105/293 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TTC37 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 112/409 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TULP4 | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 106/154 reads (69%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.005); called by mutect2, varscan2
- UBR5 | c.7120C>T p.P2374S | Missense Mutation (SNP) | VAF 200/380 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- UNC13A | c.2856G>A p.R952= | Splice Region (SNP) | VAF 88/244 reads (36%) | called by muse, mutect2, varscan2
- UNC80 | c.9487C>T p.L3163F | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UQCC1 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 140/378 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- USP42 | c.-12C>T | Splice Region (SNP) | VAF 60/179 reads (34%) | called by muse, mutect2, varscan2
- VOPP1 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 83/285 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- VWA5B1 | c.3538G>A p.E1180K (on ENST00000375079; = p.E1175K on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 200/470 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, varscan2
- VWDE | c.2839G>A p.V947I | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- WDFY4 | c.6948G>A p.K2316= | Splice Region (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- WDFY4 | c.7781G>T p.R2594L | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR53 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 102/313 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR87 | c.7853C>T p.A2618V | Missense Mutation (SNP) | VAF 157/467 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- XAB2 | c.2060T>C p.I687T | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- XDH | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XPNPEP2 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 107/140 reads (76%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- XPO1 | c.785A>T p.N262I | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- YTHDC2 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ZBED9 | c.3034T>C p.S1012P | Missense Mutation (SNP) | VAF 198/266 reads (74%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.91); called by muse, varscan2
- ZDBF2 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 141/402 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, varscan2
- ZDHHC17 | c.1326T>A p.C442* | Nonsense Mutation (SNP) | VAF 79/259 reads (31%) | called by muse, mutect2, varscan2
- ZNF215 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ZNF257 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ZNF257 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- ZNF391 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 161/430 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZNF469 | c.9679C>T p.P3227S (on ENST00000437464; = p.P3255S on NM_001367624.2) | Missense Mutation (SNP) | VAF 131/422 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF536 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 152/435 reads (35%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF578 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 119/331 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF609 | c.2971C>T p.H991Y | Missense Mutation (SNP) | VAF 148/649 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ZNF723 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF728 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.537); called by muse, varscan2
- ZP4 | c.694T>A p.F232I | Missense Mutation (SNP) | VAF 122/325 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- A2ML1 | c.1689C>T p.S563= | Silent (SNP) | VAF 85/234 reads (36%) | called by muse, mutect2, varscan2
- ABCG1 | c.681C>T p.I227= | Silent (SNP) | VAF 158/439 reads (36%) | catalogued as rs574794167, COSV59209919; called by muse, mutect2, varscan2
- ABLIM3 | c.1026G>A p.E342= | Silent (SNP) | VAF 90/156 reads (58%) | catalogued as rs1226527555; called by muse, varscan2
- ACSL5 | c.177T>A p.V59= (on ENST00000354273; = p.V115= on NM_016234.3) | Silent (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- ACSM2A | c.1269C>T p.F423= (on ENST00000219054; = p.F344= on NM_001308169.2) | Silent (SNP) | VAF 100/304 reads (33%) | called by muse, mutect2, varscan2
- ACTC1 | c.87C>T p.P29= | Silent (SNP) | VAF 112/460 reads (24%) | catalogued as COSV51758525; called by muse, varscan2
- ACTL9 | c.876G>A p.K292= | Silent (SNP) | VAF 138/419 reads (33%) | catalogued as COSV61004509; called by muse, mutect2, varscan2
- ACTN1 | c.1249C>T p.L417= | Silent (SNP) | VAF 88/273 reads (32%) | catalogued as rs767263937; called by muse, mutect2, varscan2
- ADAM32 | c.1686C>T p.F562= | Silent (SNP) | VAF 114/260 reads (44%) | called by muse, varscan2
- ADAMTS20 | c.2109C>T p.S703= | Silent (SNP) | VAF 90/243 reads (37%) | catalogued as rs1269463632; called by muse, mutect2, varscan2
- ADD2 | c.438C>T p.L146= | Silent (SNP) | VAF 110/329 reads (33%) | catalogued as COSV52471017; called by muse, mutect2, varscan2
- ADPRHL1 | c.5169G>A p.R1723= | Silent (SNP) | VAF 170/708 reads (24%) | called by muse, varscan2
- AKR1C2 | c.267C>T p.S89= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- ANAPC1 | c.3141C>T p.V1047= | Silent (SNP) | VAF 97/289 reads (34%) | called by muse, mutect2, varscan2
- ANK1 | c.4866G>A p.E1622= | Silent (SNP) | VAF 46/292 reads (16%) | called by muse, mutect2, varscan2
- ANKRD1 | c.69C>T p.F23= | Silent (SNP) | VAF 122/241 reads (51%) | called by muse, mutect2, varscan2
- ANKRD27 | c.975C>T p.I325= | Silent (SNP) | VAF 75/224 reads (33%) | catalogued as rs1308928336; called by muse, mutect2, varscan2
- ANO4 | c.2769G>A p.L923= (on ENST00000392977 / NM_001286615.2; = p.L888= on NM_178826.4) | Silent (SNP) | VAF 134/435 reads (31%) | catalogued as rs771876334, COSV54605607; called by muse, varscan2
- AREL1 | c.1125C>T p.R375= | Silent (SNP) | VAF 100/312 reads (32%) | called by muse, mutect2, varscan2
- ARID3A | c.672T>C p.T224= | Silent (SNP) | VAF 136/421 reads (32%) | called by muse, mutect2, varscan2
365 further variants in this file (0 protein-altering or splice-affecting, 324 silent, 41 other) are not listed here.
